Gene-level copy-number profile of tumor specimen TCGA-CX-7086-01A from TCGA case TCGA-CX-7086, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 53.2 years (19,434 days).
Specimen TCGA-CX-7086-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.68f9a011-2bfd-45ca-a9af-2586b5f4f402.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CX-7086-10D (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff65199d-9d39-48a7-8e2f-90f18b736586

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,234; copy number 2: 12,197; copy number 3: 23,422; copy number 4: 16,708; copy number 5: 4,603; copy number 6: 803; copy number 7: 675; copy number 8: 4; copy number 9: 1; copy number 11: 31; copy number 15: 15; copy number 16: 66; copy number 21: 30; copy number 24: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CX-7086-01A-11D-2077-01): tumor purity 0.7, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:2,041,900–2,046,023, 1 gene: AL359076.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 844 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,221,070–44,355,260, 1 gene, copy number 9 (within-gene range 5–9): ERI3.
- chr3:188,941,715–189,325,304, 4 genes, copy number 8: TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2.
- chr8:46,028,804–92,144,435, 675 genes, copy number 7 (broad region; genes not listed).
- chr11:69,294,151–72,251,288, 103 genes, copy number 15–24 (broad region; genes not listed).
- chr11:100,336,856–103,479,863, 61 genes, copy number 11–21 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
